APOLLO case AP-CRYQ — APOLLO2: Proteogenomic characterization of ovarian serous cystadenocarcinoma (APOLLO-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/93c0679d-82a3-4b63-a7a4-08281c0b17bc

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 71 years; Vital status: Alive.

Diagnoses (1)
1. High-grade serous carcinoma: Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Classification of tumor: primary; Age at diagnosis: 63.2 years (23,093 days); Residual disease: R1.

Biospecimens (2 samples)
- Sample AP-CRYQ_normal: Tissue type: Normal; Specimen type: Peripheral Blood NOS; Preservation method: Frozen.
- Sample AP-CRYQ_tumor: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Ovary; Preservation method: OCT; Diagnosis pathologically confirmed: Yes.
